Somatic mutation profile of tumor specimen TCGA-DQ-5624-01A (aliquot TCGA-DQ-5624-01A-01D-1870-08) from TCGA case TCGA-DQ-5624, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 43.4 years (15,867 days).
Specimen TCGA-DQ-5624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0c37738-d9a7-4d57-853d-b28b4b678807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-5624-10A (Blood Derived Normal), aliquot TCGA-DQ-5624-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3970a36f-06bf-4c84-89df-9c93176d007c

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, Nonsense Mutation 7, In Frame Del 1, Intron 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99326940; called by muse, mutect2, varscan2
- ADAMTS10 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as COSV99546859, COSV99547034; called by muse, mutect2
- ADCY3 | c.3250C>T p.Q1084* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99568179; called by muse, mutect2, varscan2
- ARHGEF17 | c.1237T>C p.W413R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV99735498; called by muse, mutect2, varscan2
- ASAP1 | c.1918G>T p.V640F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100727205; called by muse, mutect2, varscan2
- BPTF | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866805175, COSV100074830; called by muse, mutect2, varscan2
- CCNK | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV101110390; called by muse, mutect2, varscan2
- CDH8 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756444360, COSV100181260; called by muse, mutect2, varscan2
- CDNF | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV101012369; called by muse, mutect2, varscan2
- CLDN9 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100172154; called by muse, mutect2, varscan2
- COX19 | c.35T>A p.F12Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100700417; called by muse, mutect2
- DDX60L | c.4148C>G p.S1383C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as COSV99487555; called by muse, mutect2, varscan2
- DGKB | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs772215117, COSV51772068; called by muse, mutect2, varscan2
- DNAH9 | c.3349C>T p.H1117Y | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52359986, COSV99305653; called by muse, mutect2
- DPYS | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs957809439, COSV60910943; called by muse, mutect2
- DYNC1H1 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100794814; called by muse, mutect2, varscan2
- EXD1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527801980, COSV59254288; called by muse, mutect2, varscan2
- FAM71F2 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV101100685, COSV66352309; called by muse, mutect2
- FGA | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1309799184, COSV100120357; called by muse, mutect2, varscan2
- FMN2 | c.2441C>G p.P814R | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.293); catalogued as COSV100144816; called by muse, mutect2
- GAD2 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as COSV99393172; called by muse, mutect2, varscan2
- GEMIN5 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV99593847; called by muse, mutect2, varscan2
- GHR | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.498); catalogued as COSV100050596; called by muse, mutect2, varscan2
- GPR20 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs150478338; called by muse, mutect2
- GRIA2 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV52399705; called by muse, mutect2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HLTF | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV100026829; called by muse, mutect2
- HUWE1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99472043; called by muse, mutect2
- INPP5J | c.2528C>T p.S843F (on ENST00000331075 / NM_001284285.2; = p.S475F on NM_001002837.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV99311615; called by muse, mutect2, varscan2
- LIN28B | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV61497665; called by muse, mutect2
- LRBA | c.6641G>A p.R2214Q | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs771140734, COSV100841470; called by muse, mutect2
- MAGI2 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100834403, COSV100835476; called by muse, mutect2
- MAP3K20 | c.1343C>G p.P448R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.564); catalogued as COSV100919477, COSV100919488; called by muse, mutect2, varscan2
- MDN1 | c.5044C>T p.Q1682* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV101021245; called by muse, mutect2, varscan2
- MEFV | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs775663363, COSV99560307; ClinVar: uncertain significance; called by muse, mutect2
- MROH9 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100882755; called by muse, mutect2, varscan2
- MYCBP2 | c.4417G>C p.E1473Q (on ENST00000357337; = p.E1511Q on NM_015057.5) | Missense Mutation (SNP) | VAF 14/411 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100628834, COSV100630229; called by muse, mutect2
- MYH10 | c.5479G>C p.E1827Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99345095; called by muse, mutect2
- NDUFAF7 | c.1080A>T p.L360F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778647180, COSV99135526; called by muse, mutect2, varscan2
- NLRP1 | c.1562G>A p.W521* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99333977; called by muse, mutect2
- NOLC1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100893652; called by muse, mutect2, varscan2
- NOX1 | c.490-1G>A p.X164_splice | Splice Site (SNP) | VAF 30/281 reads (11%) | catalogued as rs1485976653, COSV99471555; called by muse, mutect2, varscan2
- OR10G4 | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV100304813; called by muse, mutect2, varscan2
- OR4D2 | c.53C>G p.S18W | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs568882234, COSV101613854; called by muse, mutect2, varscan2
- OR51A2 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100985052; called by muse, mutect2, varscan2
- PACSIN2 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99606179; called by muse, mutect2, varscan2
- PCDHAC2 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782150880, COSV99146684; called by muse, mutect2, varscan2
- PDAP1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1300722315, COSV100627211; called by mutect2, varscan2
- RYR1 | c.6343G>A p.E2115K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); catalogued as rs147197176; ClinVar: uncertain significance; called by mutect2, varscan2
- SAT1 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100803871; called by muse, mutect2, varscan2
- SCEL | c.1913A>G p.E638G (on ENST00000349847 / NM_144777.3; = p.E618G on NM_003843.4) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100582873; called by muse, mutect2
- SEMA4G | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV99272367; called by muse, varscan2
- SETD2 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV57433188, COSV57436268; called by muse, mutect2, varscan2
- SHROOM3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs758739144, COSV56029547; called by muse, mutect2, varscan2
- SI | c.4349T>G p.V1450G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100015334; called by muse, mutect2, varscan2
- SOS2 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99366000; called by muse, mutect2, varscan2
- SSRP1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV99554890; called by muse, mutect2, varscan2
- SVEP1 | c.8005G>A p.A2669T | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99928934; called by muse, mutect2, varscan2
- SYCP2L | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV99305109; called by muse, mutect2, varscan2
- TEX13A | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100781226; called by muse, mutect2, varscan2
- TP53 | c.662_665dup p.P223Afs*3 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as COSV99435175; called by mutect2, pindel
- TSHZ2 | c.1901T>C p.F634S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100296021; called by muse, mutect2, varscan2
- ZBTB8A | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100331349; called by muse, mutect2
- ZDBF2 | c.5624A>G p.K1875R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs201770559, COSV100984743, COSV65621521; called by muse, mutect2, varscan2
- ZFR2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773375916, COSV99507341; called by muse, mutect2, varscan2
- ARHGAP44 | c.1512C>A p.Y504* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- PEX14 | c.408_410del p.G138del | In Frame Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ATP6V0E2 | c.162C>T p.I54= (on ENST00000425642; = p.I103= on NM_145230.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs769202204, COSV101374582; called by muse, mutect2, varscan2
- C12orf50 | c.78C>A p.I26= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1468359938, COSV100072212; called by muse, mutect2, varscan2
- CFH | c.3153G>A p.P1051= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100809476; called by muse, mutect2
- FANCD2 | c.1158C>T p.F386= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99811161; called by muse, mutect2, varscan2
- FGD4 | c.2196G>A p.L732= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99847026; called by muse, mutect2
- FITM2 | c.517C>T p.L173= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV101201995; called by muse, mutect2
- GFPT1 | c.1386G>A p.V462= (on ENST00000357308 / NM_001244710.2; = p.V444= on NM_002056.4) | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV100622810; called by muse, mutect2, varscan2
- HNRNPA1 | c.48C>G p.L16= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV99267611; called by muse, mutect2
- ITIH6 | c.1992G>A p.V664= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54486498; called by muse, mutect2, varscan2
- KCNK9 | c.366G>A p.L122= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1457963355, COSV100270895; called by muse, mutect2, varscan2
- KIAA1210 | c.4626A>G p.Q1542= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs773994103, COSV101274107; called by muse, mutect2, varscan2
- KIAA2026 | c.2853G>A p.K951= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV101199012; called by muse, mutect2
- LEPR | c.1362C>T p.I454= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100756562; called by muse, mutect2, varscan2
- LRRC14B | c.1293C>T p.P431= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs775219349, COSV99722985; called by muse, mutect2, varscan2
- MDH1B | c.993G>A p.E331= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100982178, COSV65591532; called by muse, varscan2
- NAPA | c.24G>A p.A8= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99645717; called by muse, mutect2, varscan2
- OAZ2 | c.270C>T p.V90= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV100386422; called by muse, mutect2, varscan2
- OR52A5 | c.627C>A p.I209= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100263382; called by muse, mutect2, varscan2
- PGAP4 | c.48G>A p.R16= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs757715900, COSV100877828; called by muse, mutect2, varscan2
- RYR1 | c.2488C>A p.R830= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as CM157084, COSV100615557; called by muse, mutect2, varscan2
- S100A7 | c.111G>A p.K37= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs747673718, COSV100906735; called by muse, mutect2
- SLITRK2 | c.570G>A p.G190= | Silent (SNP) | VAF 11/162 reads (7%) | catalogued as rs1294808258, COSV100157701, COSV59426064; called by muse, mutect2
- SVEP1 | c.6693T>C p.C2231= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV99928937; called by muse, mutect2, varscan2
- TTN | c.68655G>A p.L22885= (on ENST00000591111; = p.L15461= on NM_003319.4) | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100610591; called by muse, mutect2
- MAP4 | c.1999+5295C>T | Intron (SNP) | VAF 32/250 reads (13%) | catalogued as rs772355125, COSV99275274; called by muse, mutect2, varscan2
- POLR3D | chr8:22244987 C>T | 5'Flank (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
